Somatic mutation profile of tumor specimen 0DO7ME from CCDI case PBCCEA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Schwannoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,456 days).
Specimen 0DO7ME: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5285ce41-2eba-40fe-880f-c408fb390717.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO7LX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/488913c7-98d8-4fc9-8fa2-1658aec967cb

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO9A | c.3418A>G p.K1140E | Missense Mutation (SNP) | VAF 20/482 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as COSV61847656, COSV61858289; called by muse, mutect2
- REPS1 | c.1700G>A p.R567Q (on ENST00000450536 / NM_001286611.2; = p.R566Q on NM_031922.4) | Missense Mutation (SNP) | VAF 61/409 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
